Somatic mutation profile of cancer-model specimen HCM-BROD-0568-C15-85M (3D Organoid, passage 5; aliquot HCM-BROD-0568-C15-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0568-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Age at diagnosis: 63.8 years (23,288 days).
Specimen HCM-BROD-0568-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89ed78a9-2a79-47c3-b6a2-fe4aa2ceea79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0568-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0568-C15-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6a288892-05b8-44d8-82cc-a9869f8fed3b

The open-access MAF lists 196 somatic variants for this specimen: 145 protein-altering or splice-affecting, 47 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 47, Nonsense Mutation 7, Intron 3, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 2, Splice Region 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.746G>T p.R249M | Missense Mutation (SNP) | VAF 191/191 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as rs587782329, COSV52666526, COSV52668050, COSV52697169, COSV52713804; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1891G>T p.A631S | Missense Mutation (SNP) | VAF 50/332 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV55948233; called by muse, mutect2, varscan2
- ADRA2C | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 132/428 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100342848, COSV57466824, COSV57467981; called by muse, mutect2, varscan2
- AHNAK2 | c.11146G>A p.G3716S | Missense Mutation (SNP) | VAF 158/490 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs761507427; called by muse, mutect2, varscan2
- ARAP3 | c.1157A>C p.H386P | Missense Mutation (SNP) | VAF 233/238 reads (98%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs765300785, COSV53349491; called by mutect2, varscan2
- BEND5 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 141/141 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.992); catalogued as rs776938575, COSV65717014; called by muse, mutect2, varscan2
- CACNA1E | c.3644G>T p.G1215V | Missense Mutation (SNP) | VAF 110/335 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100701223; called by muse, mutect2, varscan2
- CCDC148 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 184/295 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs200836240, COSV51757936; called by muse, mutect2, varscan2
- CFAP61 | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 189/190 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1029822950, COSV55634568; called by muse, mutect2, varscan2
- COL5A1 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 205/346 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0.224); catalogued as rs1399973685, COSV100880286; called by muse, mutect2, varscan2
- CPZ | c.1147G>T p.D383Y (on ENST00000360986 / NM_001014447.3; = p.D372Y on NM_003652.3) | Missense Mutation (SNP) | VAF 126/422 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59924014; called by muse, mutect2, varscan2
- CRYBB2 | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM132553, COSV68005773; called by muse, mutect2, varscan2
- CSMD3 | c.3680G>A p.R1227Q (on ENST00000297405 / NM_001363185.1; = p.R1123Q on NM_052900.3) | Missense Mutation (SNP) | VAF 168/389 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1411756886, COSV99825676; called by muse, mutect2, varscan2
- CYP4A11 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 148/149 reads (99%) | SIFT tolerated (0.71); PolyPhen benign (0.025); catalogued as rs144065752, COSV60225915; called by muse, mutect2, varscan2
- DNAH2 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 200/200 reads (100%) | catalogued as rs1247906703, COSV99318503; called by muse, mutect2, varscan2
- EFCAB8 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 645/645 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566866666; called by muse, mutect2, varscan2
- ENPP7 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 319/443 reads (72%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.026); catalogued as rs141369724; called by muse, mutect2, varscan2
- EPHA5 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV56682832; called by muse, mutect2, varscan2
- FAM20C | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 446/911 reads (49%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.017); catalogued as rs537240435; called by muse, mutect2
- FBN3 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 196/196 reads (100%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.616); catalogued as rs764597553, COSV54477421; called by muse, mutect2, varscan2
- GAS7 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 108/171 reads (63%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.355); catalogued as rs374102406; called by muse, mutect2, varscan2
- GNAS | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 1011/1011 reads (100%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.006); catalogued as rs781067546; called by muse, mutect2, varscan2
- GZMH | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 133/417 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs923264792, COSV53539311; called by muse, mutect2, varscan2
- KIAA2026 | c.2187dup p.A730Sfs*15 | Frame Shift Ins (INS) | VAF 62/112 reads (55%) | catalogued as rs749990720; called by mutect2, varscan2
- KRT76 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 723/726 reads (100%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs778532065; called by muse, mutect2, varscan2
- KRTAP16-1 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 320/796 reads (40%) | catalogued as rs765795260; called by muse, mutect2, varscan2
- LARP7 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV60521058; called by muse, mutect2, varscan2
- LRP1B | c.231C>A p.C77* | Nonsense Mutation (SNP) | VAF 62/204 reads (30%) | catalogued as COSV67199027; called by mutect2, varscan2
- MAP3K3 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 101/549 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV62282154; called by muse, mutect2, varscan2
- MDM1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 230/230 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs372443907, COSV100292076; called by muse, mutect2, varscan2
- MGAT4C | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100153028; called by muse, mutect2, varscan2
- MYO3A | c.4811G>A p.R1604H | Missense Mutation (SNP) | VAF 199/379 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99392867; called by muse, mutect2, varscan2
- NEFM | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 149/352 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.634); catalogued as COSV55332845; called by muse, mutect2, varscan2
- NEUROG1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 613/613 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.36); catalogued as COSV100130736; called by muse, mutect2, varscan2
- NFE2L1 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 355/805 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100671613; called by muse, mutect2, varscan2
- NKX2-8 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 230/675 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1405888740; called by muse, mutect2, varscan2
- OCA2 | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 160/267 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CD992272; called by muse, mutect2, varscan2
- OR10R2 | c.600C>A p.D200E | Missense Mutation (SNP) | VAF 106/325 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63768606; called by muse, mutect2, varscan2
- OR5T3 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 110/331 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV57382081; called by muse, mutect2, varscan2
- PIK3R6 | c.1879+1G>A p.X627_splice | Splice Site (SNP) | VAF 117/117 reads (100%) | catalogued as rs1242978278; called by muse, mutect2, varscan2
- PPP1R13L | c.2341G>A p.E781K | Missense Mutation (SNP) | VAF 420/420 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV104417524; called by muse, mutect2, varscan2
- PRICKLE2 | c.2170C>T p.R724C (on ENST00000295902; = p.R668C on NM_198859.4) | Missense Mutation (SNP) | VAF 228/228 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs776915714, COSV55767149; called by muse, varscan2
- PRKCQ | c.944C>A p.P315Q | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV54107787; called by muse, mutect2, varscan2
- PRKDC | c.11210G>A p.R3737H | Missense Mutation (SNP) | VAF 328/571 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs763729016; called by muse, mutect2, varscan2
- PSTK | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 98/439 reads (22%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs750134125, COSV64398319; called by muse, mutect2, varscan2
- PTPRD | c.4067A>T p.K1356M | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV61931791, COSV61957305; called by muse, mutect2, varscan2
- RNF31 | c.2075G>A p.R692H | Missense Mutation (SNP) | VAF 294/432 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs777855826; called by muse, mutect2, varscan2
- SCAI | c.832G>A p.A278T (on ENST00000336505 / NM_001144877.3; = p.A301T on NM_173690.5) | Missense Mutation (SNP) | VAF 140/228 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs369558159; called by muse, mutect2, varscan2
- SCG2 | c.1195T>G p.L399V | Missense Mutation (SNP) | VAF 240/387 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV59538910, COSV59540439; called by muse, mutect2, varscan2
- SCN9A | c.695A>C p.K232T | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57617191; called by muse, mutect2, varscan2
- SERTAD2 | c.264del p.S89Pfs*108 | Frame Shift Del (DEL) | VAF 149/575 reads (26%) | catalogued as COSV100512274; called by mutect2, pindel, varscan2
- SLC16A11 | c.928C>T p.R310W (on ENST00000308009; = p.R286W on NM_153357.3) | Missense Mutation (SNP) | VAF 538/540 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs748518579; called by muse, mutect2, varscan2
- SP100 | c.1607dup p.R537Efs*4 | Frame Shift Ins (INS) | VAF 96/285 reads (34%) | catalogued as rs755117277; called by mutect2, pindel, varscan2
- SPAG16 | c.1687A>C p.S563R | Missense Mutation (SNP) | VAF 85/130 reads (65%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.941); catalogued as rs1278165214, COSV100530109, COSV100536780; called by muse, mutect2, varscan2
- SPOCK1 | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 111/325 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV56460006; called by muse, mutect2, varscan2
- TAS1R3 | c.1426G>C p.G476R | Missense Mutation (SNP) | VAF 338/338 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.414); catalogued as COSV59566441; called by muse, mutect2, varscan2
- TBX18 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 138/231 reads (60%) | catalogued as rs202211205; called by muse, mutect2, varscan2
- TMCO4 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 166/166 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs146596460; called by muse, mutect2, varscan2
- TNR | c.2008A>C p.M670L | Missense Mutation (SNP) | VAF 105/370 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99690260; called by muse, mutect2, varscan2
- TRIM9 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 413/608 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0.079); catalogued as rs1447026513; called by muse, mutect2, varscan2
- TTLL4 | c.2750C>T p.S917F | Missense Mutation (SNP) | VAF 148/246 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51438743; called by muse, mutect2, varscan2
- TTN | c.7402G>C p.V2468L (on ENST00000591111; = p.V2422L on NM_003319.4) | Missense Mutation (SNP) | VAF 77/318 reads (24%) | PolyPhen benign (0.013); catalogued as rs1420278166; called by muse, mutect2, varscan2
- VIPR1 | c.518C>T p.T173M | Missense Mutation (SNP) | VAF 84/275 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs751164992, COSV57298289; called by muse, mutect2, varscan2
- WDFY3 | c.5843G>T p.G1948V | Missense Mutation (SNP) | VAF 191/306 reads (62%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV55705551; called by muse, mutect2, varscan2
- ZBTB37 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 101/377 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.952); catalogued as COSV62931377, COSV62934340; called by muse, mutect2, varscan2
- ZNF468 | c.1366C>A p.Q456K | Missense Mutation (SNP) | VAF 145/290 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.009); catalogued as rs748000875; called by muse, mutect2, varscan2
- ZNF692 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 87/290 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs771914078; called by muse, mutect2, varscan2
- ZSCAN1 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 353/353 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs145743431, COSV56603241; called by muse, mutect2, varscan2
- ADGRB1 | c.2728C>T p.R910C | Missense Mutation (SNP) | VAF 451/763 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ADGRB1 | c.4285C>T p.P1429S | Missense Mutation (SNP) | VAF 90/483 reads (19%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, varscan2
- AFF2 | c.2401C>A p.L801I | Missense Mutation (SNP) | VAF 143/506 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ALS2CL | c.1376A>T p.Y459F | Missense Mutation (SNP) | VAF 146/629 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- ANKRD30B | c.338C>A p.A113D | Missense Mutation (SNP) | VAF 170/352 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ARHGEF9 | c.1495C>G p.R499G | Missense Mutation (SNP) | VAF 274/449 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- ATP13A5 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 131/276 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf92 | c.148+1G>A p.X50_splice | Splice Site (SNP) | VAF 138/252 reads (55%) | called by muse, mutect2, varscan2
- CCDC15 | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CDH18 | c.1165C>G p.L389V | Missense Mutation (SNP) | VAF 81/538 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDK5R2 | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 210/663 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CEP295 | c.3199C>A p.Q1067K | Missense Mutation (SNP) | VAF 156/226 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CLEC1A | c.636G>A p.M212I | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CNTN3 | c.2276C>A p.P759Q | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- COLQ | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 231/333 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CUL7 | c.2924C>T p.P975L | Missense Mutation (SNP) | VAF 150/540 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPHB1 | c.2375C>A p.A792D | Missense Mutation (SNP) | VAF 87/368 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- EPN3 | c.1732T>A p.S578T | Missense Mutation (SNP) | VAF 279/1077 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- EVX2 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 278/801 reads (35%) | called by muse, mutect2, varscan2
- FAM20C | c.1404T>G p.F468L | Missense Mutation (SNP) | VAF 299/618 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAT4 | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 157/246 reads (64%) | SIFT tolerated (0.26); PolyPhen benign (0.329); called by muse, mutect2, varscan2
- FAT4 | c.2771T>C p.V924A | Missense Mutation (SNP) | VAF 79/223 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- FCMR | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 118/362 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- FMO2 | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 222/329 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FOXP2 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 186/863 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GLI3 | c.3061G>T p.V1021L | Missense Mutation (SNP) | VAF 419/1366 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- GRAMD1B | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 185/891 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- GRM5 | c.1689A>C p.T563= | Splice Region (SNP) | VAF 76/366 reads (21%) | called by muse, mutect2, varscan2
- GSG1 | c.8A>T p.D3V | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- GUCY1B1 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 84/126 reads (67%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- HERC2 | c.9929A>T p.K3310M | Missense Mutation (SNP) | VAF 193/691 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- HMCN2 | c.12932A>G p.D4311G | Missense Mutation (SNP) | VAF 149/376 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- HOOK2 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 102/527 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- IL18RAP | c.169T>C p.C57R | Missense Mutation (SNP) | VAF 118/428 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LAD1 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 125/411 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LHX3 | c.634_636del p.E212del (on ENST00000371748 / NM_178138.6; = p.E217del on NM_014564.5) | In Frame Del (DEL) | VAF 129/393 reads (33%) | called by mutect2, pindel, varscan2
- LIFR | c.1657A>G p.I553V | Missense Mutation (SNP) | VAF 130/236 reads (55%) | SIFT tolerated (0.44); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- LOXHD1 | c.3020T>G p.L1007R | Missense Mutation (SNP) | VAF 284/284 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- LRCH4 | c.858G>T p.E286D | Missense Mutation (SNP) | VAF 102/942 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- LZTS3 | c.1697G>T p.G566V (on ENST00000329152; = p.G520V on NM_001282533.2) | Missense Mutation (SNP) | VAF 205/440 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- MLXIPL | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 122/626 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MPPED2 | c.803A>C p.K268T | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYH1 | c.2116A>G p.I706V | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- MYH9 | c.5585A>C p.K1862T | Missense Mutation (SNP) | VAF 256/257 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- MYOCD | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MYT1L | c.3068A>G p.H1023R | Missense Mutation (SNP) | VAF 153/311 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NAALADL1 | c.1324A>G p.I442V | Missense Mutation (SNP) | VAF 278/561 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- NCEH1 | c.1324A>C p.K442Q (on ENST00000538775; = p.K402Q on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/296 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NIN | c.5824G>C p.E1942Q (on ENST00000382041 / NM_182946.1; = p.E1229Q on NM_016350.4) | Missense Mutation (SNP) | VAF 90/293 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NRG3 | c.785C>A p.T262N | Missense Mutation (SNP) | VAF 88/409 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ODF2L | c.1687C>A p.L563I (on ENST00000317336; = p.L547I on NM_020729.3) | Missense Mutation (SNP) | VAF 238/238 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- OPA1 | c.2474A>G p.D825G (on ENST00000361510 / NM_130837.3; = p.D770G on NM_015560.3) | Missense Mutation (SNP) | VAF 147/310 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1C1 | c.291C>A p.C97* | Nonsense Mutation (SNP) | VAF 67/212 reads (32%) | called by muse, mutect2, varscan2
- OR2H2 | c.282C>A p.D94E | Missense Mutation (SNP) | VAF 215/662 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR5W2 | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 138/224 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR6K2 | c.647T>C p.F216S | Missense Mutation (SNP) | VAF 68/269 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLEC | c.6113C>T p.A2038V (on ENST00000322810 / NM_201380.4; = p.A1928V on NM_000445.5) | Missense Mutation (SNP) | VAF 230/1252 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PRAMEF2 | c.1363del p.T455Pfs*41 | Frame Shift Del (DEL) | VAF 24/163 reads (15%) | called by mutect2, varscan2
- PRMT6 | c.377T>C p.F126S | Missense Mutation (SNP) | VAF 58/800 reads (7%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- PRMT8 | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 466/468 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PZP | c.1594C>A p.P532T | Missense Mutation (SNP) | VAF 94/381 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGPD3 | c.3245T>C p.L1082S | Missense Mutation (SNP) | VAF 298/488 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SCN9A | c.604A>C p.T202P | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEC23B | c.1089G>C p.K363N | Missense Mutation (SNP) | VAF 136/136 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SEMA3D | c.1082G>C p.S361T | Missense Mutation (SNP) | VAF 225/310 reads (73%) | SIFT tolerated (0.32); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SHCBP1L | c.1203C>A p.D401E | Missense Mutation (SNP) | VAF 75/199 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SOX1 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 117/299 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- ST18 | c.2667C>T p.S889= | Splice Region (SNP) | VAF 165/312 reads (53%) | called by muse, mutect2, varscan2
- TBCD | c.3170A>T p.D1057V | Missense Mutation (SNP) | VAF 87/350 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TCEAL5 | c.33G>T p.K11N | Missense Mutation (SNP) | VAF 321/323 reads (99%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCF15 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TCP11L2 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 226/226 reads (100%) | called by muse, mutect2, varscan2
- THAP6 | c.322T>G p.F108V | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TIGD6 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 327/327 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM67 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 523/821 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TTN | c.42997G>T p.V14333F (on ENST00000591111; = p.V6909F on NM_003319.4) | Missense Mutation (SNP) | VAF 203/309 reads (66%) | PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ZDHHC21 | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ABCC4 | c.867C>T p.Y289= | Silent (SNP) | VAF 55/250 reads (22%) | catalogued as rs371626444; called by muse, mutect2, varscan2
- ABHD12 | c.1182C>T p.S394= | Silent (SNP) | VAF 227/227 reads (100%) | called by muse, mutect2, varscan2
- AGBL5 | c.360A>G p.E120= | Silent (SNP) | VAF 232/451 reads (51%) | called by muse, mutect2, varscan2
- BDKRB2 | c.729C>T p.C243= | Silent (SNP) | VAF 139/443 reads (31%) | called by muse, mutect2
- CACNA1I | c.174C>T p.A58= | Silent (SNP) | VAF 432/433 reads (100%) | called by muse, mutect2, varscan2
- CELSR1 | c.5313C>T p.D1771= | Silent (SNP) | VAF 362/362 reads (100%) | catalogued as rs745930956; called by muse, mutect2, varscan2
- CES5A | c.465C>A p.S155= | Silent (SNP) | VAF 129/337 reads (38%) | called by muse, mutect2, varscan2
- CHST5 | c.1074G>A p.A358= | Silent (SNP) | VAF 412/413 reads (100%) | catalogued as rs764453614, COSV100292113; called by muse, mutect2, varscan2
- CYBRD1 | c.69G>T p.S23= | Silent (SNP) | VAF 181/553 reads (33%) | called by muse, mutect2, varscan2
- DNAH7 | c.2911C>T p.L971= | Silent (SNP) | VAF 78/267 reads (29%) | called by muse, mutect2, varscan2
- DYSF | c.1780C>T p.L594= | Silent (SNP) | VAF 226/307 reads (74%) | called by muse, mutect2, varscan2
- FAM20C | c.1608C>T p.P536= | Silent (SNP) | VAF 487/1079 reads (45%) | catalogued as rs746323195; called by muse, mutect2, varscan2
- FRMPD4 | c.3648T>A p.S1216= | Silent (SNP) | VAF 159/495 reads (32%) | called by muse, mutect2, varscan2
- FSTL5 | c.1203C>T p.S401= | Silent (SNP) | VAF 127/213 reads (60%) | catalogued as COSV60222432; called by muse, mutect2, varscan2
- FZD8 | c.1293C>T p.N431= | Silent (SNP) | VAF 171/312 reads (55%) | called by muse, mutect2, varscan2
- FZD9 | c.366C>T p.C122= | Silent (SNP) | VAF 459/625 reads (73%) | called by muse, mutect2, varscan2
- G6PC3 | c.549C>A p.G183= | Silent (SNP) | VAF 75/450 reads (17%) | catalogued as COSV52242443; called by muse, mutect2, varscan2
- GBA3 | c.117A>T p.G39= | Silent (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- GCSAML | c.264C>A p.G88= | Silent (SNP) | VAF 103/379 reads (27%) | called by muse, mutect2, varscan2
- GRIK4 | c.970C>A p.R324= | Silent (SNP) | VAF 278/583 reads (48%) | called by muse, mutect2, varscan2
- HAP1 | c.1671G>A p.A557= (on ENST00000310778 / NM_001367460.1; = p.A505= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 428/1078 reads (40%) | catalogued as rs141752762; called by muse, mutect2
- HS3ST3A1 | c.324C>T p.G108= | Silent (SNP) | VAF 314/315 reads (100%) | catalogued as COSV99404629; called by muse, mutect2, varscan2
- HSPA2 | c.873C>T p.Y291= | Silent (SNP) | VAF 131/418 reads (31%) | catalogued as COSV55969058; called by muse, mutect2, varscan2
- KLHL29 | c.606C>A p.G202= | Silent (SNP) | VAF 173/806 reads (21%) | called by muse, mutect2, varscan2
- LIFR | c.363T>C p.S121= | Silent (SNP) | VAF 131/283 reads (46%) | catalogued as COSV54702474; called by muse, mutect2, varscan2
- MAN2A2 | c.222C>T p.S74= | Silent (SNP) | VAF 283/417 reads (68%) | catalogued as rs550546703; called by muse, mutect2, varscan2
- MAP1B | c.1443G>A p.A481= | Silent (SNP) | VAF 326/327 reads (100%) | catalogued as rs533759374, COSV57106226; called by muse, mutect2, varscan2
- MAPKBP1 | c.1851G>A p.T617= (on ENST00000456763 / NM_001128608.2; = p.T611= on NM_014994.3) | Silent (SNP) | VAF 169/311 reads (54%) | catalogued as rs749115120; called by muse, mutect2, varscan2
- MCC | c.2484G>A p.S828= | Silent (SNP) | VAF 214/214 reads (100%) | catalogued as rs753720758, COSV100203161; called by muse, mutect2, varscan2
- MYH13 | c.5391G>T p.L1797= | Silent (SNP) | VAF 205/205 reads (100%) | catalogued as COSV99355326; called by muse, mutect2, varscan2
- OLIG3 | c.339G>A p.A113= | Silent (SNP) | VAF 152/502 reads (30%) | catalogued as rs142649210, COSV100880293, COSV62988200; called by muse, mutect2, varscan2
- PCDHA11 | c.1911C>T p.D637= | Silent (SNP) | VAF 345/346 reads (100%) | catalogued as COSV56484125; called by muse, mutect2, varscan2
- PCSK5 | c.4356C>T p.N1452= | Silent (SNP) | VAF 137/349 reads (39%) | catalogued as rs761986891, COSV70447772; called by muse, mutect2, varscan2
- PROX1 | c.1521A>G p.K507= | Silent (SNP) | VAF 146/442 reads (33%) | catalogued as COSV54783307, COSV99799700; called by muse, mutect2, varscan2
- RAB9B | c.411G>A p.E137= | Silent (SNP) | VAF 170/293 reads (58%) | catalogued as COSV99686056; called by muse, mutect2, varscan2
- RBM25 | c.2472C>A p.V824= | Silent (SNP) | VAF 95/168 reads (57%) | called by muse, mutect2, varscan2
- SAMD15 | c.1125A>G p.P375= | Silent (SNP) | VAF 96/351 reads (27%) | called by muse, mutect2
- SDK2 | c.2175T>G p.G725= | Silent (SNP) | VAF 80/423 reads (19%) | called by muse, mutect2, varscan2
- SEMG1 | c.639T>C p.S213= | Silent (SNP) | VAF 89/521 reads (17%) | called by muse, mutect2, varscan2
- SHISA6 | c.114C>T p.G38= | Silent (SNP) | VAF 106/162 reads (65%) | catalogued as rs1333076237; called by muse, varscan2
- SSTR1 | c.237C>T p.V79= | Silent (SNP) | VAF 131/402 reads (33%) | catalogued as COSV57457697; called by muse, mutect2, varscan2
- TATDN2 | c.1533C>T p.F511= | Silent (SNP) | VAF 111/366 reads (30%) | catalogued as COSV55050910; called by muse, mutect2, varscan2
- TBX20 | c.48C>T p.N16= | Silent (SNP) | VAF 301/658 reads (46%) | catalogued as rs375102469, COSV101282443; called by muse, mutect2, varscan2
- TJP2 | c.2706C>G p.S902= | Silent (SNP) | VAF 80/268 reads (30%) | catalogued as rs145703764; called by muse, mutect2
- TNXB | c.8979A>T p.G2993= (on ENST00000647633; = p.G2746= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 182/610 reads (30%) | called by muse, mutect2, varscan2
- ZFPM2 | c.2610G>A p.L870= | Silent (SNP) | VAF 384/629 reads (61%) | catalogued as COSV65872571; called by muse, mutect2, varscan2
- ZNF862 | c.2340C>G p.R780= | Silent (SNP) | VAF 328/328 reads (100%) | called by muse, mutect2, varscan2
- CDC25B | c.*917G>A | 3'UTR (SNP) | VAF 144/268 reads (54%) | catalogued as rs1405084579; called by muse, mutect2, varscan2
- FBXW7 | c.502-2393A>G | Intron (SNP) | VAF 156/242 reads (64%) | called by muse, mutect2, varscan2
- HDAC9 | c.1722+13G>T | Intron (SNP) | VAF 182/439 reads (41%) | catalogued as rs1191085473; called by muse, mutect2, varscan2
- ZNF606 | c.88+173G>A | Intron (SNP) | VAF 137/137 reads (100%) | catalogued as rs750722060; called by muse, mutect2, varscan2
